Surgical pathology report (de-identified scan), TCGA case TCGA-DD-AAVX, project TCGA-LIHC (Liver Hepatocellular Carcinoma), tissue source site Mayo Clinic - Rochester, specimen TCGA-DD-AAVX-01A (Primary Tumor).

DIAGNOSIS:

Liver, right, posterior sectionectomy:

Hepatocellular carcinoma, S6/7

- 1) Post-chemoembolization status: absent
- 2) Size of tumor: 6.5x4.9x4.5cm
- 3) Gross type: expanding nodular
- 4) Satellite nodule: absent
- 5) Histologic type: trabecular/pseudoglandular
- 6) Cell type: classic
- 7) Edmondson and Steiner's histologic grade:
The worst differentiation: 2/4
The major differentiation: 2/4
- 8) Fatty change: absent
- 9) Hemorrhage/peliosis: present (5%)
- 10) Tumor necrosis: absent
- 11) Vascular invasion(microscopic): present
- 12) Capsule formation: partial
- 13) Infiltration of capsule: present
- 14) Septal formation: absent
- 15) Involvement of a major branch of the portal vein: absent
- 16) Involvement of a major branch of the hepatic vein: absent
- 17) Bile duct invasion: absent
- 18) Serosal invasion: absent
- 19) Surgical margin: free (safety margin: 3cm)
- 20) Intrahepatic metastasis: absent
- 21) Multicentric occurrence: absent
- 22) Pathologic stage: AJCC (pT2), (pT3)
- 23) Related biopsy: none
- 24) Additional pathologic findings
- a) Cirrhosis: present, active, HBV-associated
- b) Dysplasia: absent

ICD O-3
Carcinoma, hepatocellular, NOS
817013
Site: Liver C22.0
JAN 4/23/14

Gallbladder, cholecystectomy:

No diagnostic abnormalities recognized

Source: NCI Genomic Data Commons file bf711d98-e5fb-4452-8f49-29271977727d (TCGA-DD-AAVX.C62E123A-5AFC-47FA-AE6A-E16C22ACD374.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).